Somatic mutation profile of tumor specimen 0DJE39 from CCDI case PBBVWS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pleomorphic rhabdomyosarcoma, adult type; Tissue or organ of origin: Short bones of upper limb and associated joints; Age at diagnosis: 20.2 years (7,395 days).
Specimen 0DJE39: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92981a23-df97-46d2-8fc5-321a83d34093.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJE3G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3a1762d-1c05-4c11-ab4a-6bdce7ae5c26

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 3, Silent 3, Frame Shift Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBFA2T2 | c.1565A>G p.N522S | Missense Mutation (SNP) | VAF 95/849 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100656128; called by muse, mutect2, varscan2
- CHRDL1 | c.1276A>C p.S426R (on ENST00000372045; = p.S432R on NM_145234.4) | Missense Mutation (SNP) | VAF 64/525 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.585); catalogued as COSV54327041; called by muse, mutect2, varscan2
- CLSTN1 | c.2291C>T p.T764I (on ENST00000377298 / NM_001009566.3; = p.T754I on NM_014944.4) | Missense Mutation (SNP) | VAF 128/1109 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as rs753388096; called by muse, mutect2, varscan2
- EFNB3 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773356284; called by mutect2, varscan2
- CGA | c.203A>C p.K68T | Missense Mutation (SNP) | VAF 64/1074 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); called by muse, mutect2
- CSF2RA | c.647-1G>C p.X216_splice | Splice Site (SNP) | VAF 34/350 reads (10%) | called by muse, mutect2
- DLG4 | c.840del p.D281Tfs*6 (on ENST00000399506 / NM_001321075.3; = p.D324Tfs*6 on NM_001365.4) | Frame Shift Del (DEL) | VAF 74/512 reads (14%) | called by mutect2, varscan2
- KIF18A | c.1655T>C p.I552T | Missense Mutation (SNP) | VAF 109/1257 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2
- LIN7B | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.134); called by muse, mutect2
- NAB1 | c.334A>G p.S112G | Missense Mutation (SNP) | VAF 46/588 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- NIBAN1 | c.796A>T p.N266Y | Missense Mutation (SNP) | VAF 28/962 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR1A1 | c.804A>C p.K268N | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- PHF20L1 | c.1744G>T p.D582Y | Missense Mutation (SNP) | VAF 54/986 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2
- SLITRK2 | c.1769T>G p.L590W | Missense Mutation (SNP) | VAF 44/441 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.765); called by muse, mutect2
- EFNB3 | c.585C>T p.S195= | Silent (SNP) | VAF 73/399 reads (18%) | catalogued as rs1288603585; called by muse, mutect2, varscan2
- NPY5R | c.903A>G p.E301= | Silent (SNP) | VAF 95/840 reads (11%) | called by muse, mutect2, varscan2
- SGSM1 | c.1434A>G p.P478= | Silent (SNP) | VAF 22/422 reads (5%) | called by muse, mutect2
- DISP1 | c.889+71C>G | Intron (SNP) | VAF 29/171 reads (17%) | called by muse, mutect2, varscan2
- RNF40 | c.2830-100T>C | Intron (SNP) | VAF 3/23 reads (13%) | called by muse, varscan2
- SLC14A1 | c.-21-83C>A | Intron (SNP) | VAF 7/51 reads (14%) | called by muse, varscan2
- TBC1D3J | n.388T>A | RNA (SNP) | VAF 55/376 reads (15%) | called by muse, mutect2, varscan2
